Somatic mutation profile of tumor specimen C3L-01063-03 (aliquot CPT0199640006) from CPTAC case C3L-01063, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 84.4 years (30,810 days).
Specimen C3L-01063-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bfea29f-de11-4d2e-aab3-c148f50831b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01063-31 (Blood Derived Normal), aliquot CPT0200360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9fda495-7953-4b3b-af17-790b2cc6af01

The open-access MAF lists 577 somatic variants for this specimen: 379 protein-altering or splice-affecting, 173 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 324, Silent 173, Nonsense Mutation 24, Intron 16, Frame Shift Del 15, Splice Region 10, 5'Flank 6, Translation Start Site 2, Splice Site 2, In Frame Del 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 135/415 reads (33%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GATA3 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 91/307 reads (30%) | hotspot (GDC flag); catalogued as rs104894164, CM011940, COSV100651029, COSV60515523; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.313_318del p.P105_A106del | In Frame Del (DEL) | VAF 201/267 reads (75%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- STK19 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 333/673 reads (49%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs267600971, COSV61712753; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3140C>T p.S1047L | Missense Mutation (SNP) | VAF 105/322 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1308990340; called by muse, varscan2
- ACSF3 | c.1714C>T p.H572Y | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1317574765; called by muse, mutect2, varscan2
- ADAMTS20 | c.4510G>A p.G1504S | Missense Mutation (SNP) | VAF 102/329 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); catalogued as rs1178451668; called by muse, mutect2, varscan2
- AOC3 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 179/383 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs779415396, COSV99520031; called by muse, mutect2, varscan2
- ASB17 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.956); catalogued as rs755393836, COSV52410026; called by muse, mutect2
- ATP12A | c.1705G>A p.G569S | Missense Mutation (SNP) | VAF 81/242 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1310724006; called by muse, mutect2, varscan2
- BARD1 | c.994A>C p.I332L | Missense Mutation (SNP) | VAF 123/374 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs543606863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL3 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV51233884; called by muse, mutect2, varscan2
- BMP1 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 102/355 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as COSV100109893; called by muse, mutect2, varscan2
- BRINP2 | c.1325G>A p.S442N | Missense Mutation (SNP) | VAF 105/596 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV100837774; called by muse, mutect2, varscan2
- C1orf94 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 145/443 reads (33%) | catalogued as COSV64913823; called by muse, mutect2, varscan2
- CACNA1S | c.3214G>A p.G1072R | Missense Mutation (SNP) | VAF 67/440 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370439425; called by muse, mutect2, varscan2
- CARD11 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 115/371 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as COSV67802414; called by muse, mutect2, varscan2
- CASZ1 | c.2099C>T p.S700L | Missense Mutation (SNP) | VAF 135/412 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.988); catalogued as rs761954486, COSV59733484; called by muse, mutect2, varscan2
- CBLIF | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 107/318 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs1199432230, COSV57239303; called by muse, mutect2, varscan2
- CCDC197 | c.683G>A p.W228* | Nonsense Mutation (SNP) | VAF 105/320 reads (33%) | catalogued as rs1286003713; called by muse, mutect2, varscan2
- CCR3 | c.-11G>A | Splice Region (SNP) | VAF 58/151 reads (38%) | catalogued as rs780722835; called by muse, mutect2, varscan2
- CDC27 | c.1529T>A p.F510Y | Missense Mutation (SNP) | VAF 137/267 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV50364518; called by muse, mutect2, varscan2
- CDH5 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 126/359 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs369961093; called by muse, mutect2, varscan2
- CENPF | c.6685C>G p.L2229V | Missense Mutation (SNP) | VAF 85/467 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs1187779938; called by muse, mutect2, varscan2
- CENPT | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 134/437 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs776120648, COSV99535396; called by muse, mutect2, varscan2
- CFH | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 88/519 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as rs1200165780; called by muse, mutect2, varscan2
- CFP | c.1134G>A p.L378= | Splice Region (SNP) | VAF 79/275 reads (29%) | catalogued as rs752027963; called by muse, mutect2, varscan2
- CHL1 | c.2214G>A p.M738I (on ENST00000397491 / NM_001253387.1; = p.M754I on NM_006614.4) | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV99849679; called by muse, mutect2
- CHRDL1 | c.431G>A p.G144E (on ENST00000372045; = p.G150E on NM_145234.4) | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs867635832, COSV54325570; called by muse, mutect2, varscan2
- CNBD1 | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs369138086; called by muse, mutect2, varscan2
- CNNM2 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 105/403 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs766784112; called by muse, mutect2, varscan2
- CNTN5 | c.2730+5G>A | Splice Region (SNP) | VAF 75/190 reads (39%) | catalogued as COSV54293646; called by muse, mutect2, varscan2
- CNTNAP2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 85/281 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs747286104, COSV100666387, COSV100673833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A2 | c.3109C>T p.P1037S (on ENST00000341947 / NM_080680.3; = p.P930S on NM_080679.2) | Missense Mutation (SNP) | VAF 152/647 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV59502019; called by muse, mutect2, varscan2
- COL4A5 | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 118/314 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1437156555, COSV60374220; called by muse, mutect2, varscan2
- COL5A1 | c.4528G>A p.G1510S | Missense Mutation (SNP) | VAF 121/330 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65669748; called by muse, mutect2, varscan2
- COL5A3 | c.1690C>T p.Q564* | Nonsense Mutation (SNP) | VAF 91/287 reads (32%) | catalogued as rs938005016; called by muse, mutect2, varscan2
- COL8A2 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 155/489 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482002069; called by muse, mutect2, varscan2
- CPED1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 90/316 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs187314481, COSV60000351; called by muse, mutect2, varscan2
- CR1 | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 204/519 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV65455623; called by muse, mutect2
- CRISPLD1 | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 35/127 reads (28%) | catalogued as COSV51545229; called by muse, mutect2, varscan2
- CSMD1 | c.9976G>A p.G3326R (on ENST00000520002; = p.G3325R on NM_033225.6) | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59299327; called by muse, mutect2, varscan2
- DAW1 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59365551; called by muse, mutect2, varscan2
- DGKK | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 127/367 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs782712184, COSV65706174; called by muse, mutect2, varscan2
- DMGDH | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 120/360 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs765873369, COSV99669041; called by muse, mutect2
- DMGDH | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as rs145775047; called by muse, mutect2, varscan2
- DNA2 | c.2403_2404del p.R801Sfs*6 | Frame Shift Del (DEL) | VAF 48/226 reads (21%) | catalogued as rs1564877506; called by pindel, varscan2
- DNAH11 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 103/297 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as COSV60939823; called by muse, mutect2, varscan2
- DNAH12 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1207891177, COSV104418255; called by muse, mutect2, varscan2
- DNAH6 | c.6473G>A p.R2158Q | Missense Mutation (SNP) | VAF 94/269 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as rs866524152, COSV52853818; called by muse, mutect2, varscan2
- DNAH9 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 136/309 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.752); catalogued as COSV99307524; called by muse, mutect2, varscan2
- DOK5 | c.597G>A p.G199= | Splice Region (SNP) | VAF 76/244 reads (31%) | catalogued as COSV52826224; called by muse, varscan2
- DTX3L | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 139/415 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs370825525; called by muse, mutect2, varscan2
- EFHB | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 135/358 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.703); catalogued as rs1291052813; called by muse, mutect2, varscan2
- ELAVL2 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 79/256 reads (31%) | catalogued as rs867496241, COSV99805296; called by muse, mutect2, varscan2
- EMB | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 123/334 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.373); catalogued as rs375679309; called by muse, mutect2, varscan2
- ENOPH1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs374821138, COSV56731780; called by muse, mutect2, varscan2
- ERVV-2 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 147/471 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1236125975; called by muse, mutect2, varscan2
- F13A1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 82/346 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV53567400; called by muse, mutect2, varscan2
- FAM160B2 | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs761821028; called by muse, mutect2, varscan2
- FAM171A1 | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 136/399 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1281476146, COSV65314280; called by muse, mutect2, varscan2
- FAT3 | c.13408G>A p.E4470K | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as rs753317758, COSV53114577; called by muse, mutect2, varscan2
- FGD2 | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 92/444 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV51463485, COSV51464594; called by muse, mutect2, varscan2
- FGF16 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376876932, COSV101466310; called by muse, mutect2, varscan2
- FLII | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1310082563; called by muse, mutect2, varscan2
- FLNC | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 116/379 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs780144802, COSV99064155; called by muse, mutect2, varscan2
- FLT1 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); catalogued as COSV56727307; called by muse, mutect2, varscan2
- FOXD4L4 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 135/1246 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as rs1204119954; called by muse, mutect2, varscan2
- FSIP2 | c.18881C>T p.S6294L | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766201995, COSV58094425; called by muse, mutect2
- GABRG2 | c.1094C>T p.S365L (on ENST00000361925 / NM_001375343.1; = p.S325L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/285 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62717482; called by mutect2, varscan2
- GABRR2 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 164/294 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as rs1471466997, COSV101298961; called by muse, mutect2, varscan2
- GPR33 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 133/367 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs767940921; called by muse, mutect2, varscan2
- HTR1E | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.348); catalogued as COSV100541288, COSV59506492; called by muse, mutect2
- IDI2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs61738901, COSV52987214; called by muse, mutect2, varscan2
- IGHG1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 188/530 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs587700276; called by muse, mutect2, varscan2
- IGKV1-12 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 129/881 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.852); catalogued as rs932493203; called by muse, mutect2, varscan2
- IL13RA1 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 98/332 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.034); catalogued as COSV65426835; called by muse, varscan2
- KBTBD4 | c.113_114del p.C38Sfs*8 | Frame Shift Del (DEL) | VAF 79/330 reads (24%) | catalogued as rs755198870; called by pindel, varscan2
- KCNT2 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV54068824; called by muse, mutect2, varscan2
- KIAA1109 | c.3559C>T p.P1187S | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); catalogued as COSV52665026; called by muse, mutect2, varscan2
- KIF25 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 114/256 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as rs1467650613; called by muse, mutect2, varscan2
- KIF27 | c.3976_3977del p.D1326* | Frame Shift Del (DEL) | VAF 72/311 reads (23%) | catalogued as rs1460842246; called by mutect2, pindel, varscan2
- KIR3DL2 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 171/474 reads (36%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as COSV54389382; called by muse, mutect2, varscan2
- KRIT1 | c.150_151del p.K51Sfs*12 | Frame Shift Del (DEL) | VAF 59/279 reads (21%) | catalogued as rs1348650457; called by mutect2, pindel, varscan2
- KRTAP5-4 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV101294381; called by muse, varscan2
- LAMA1 | c.2066C>T p.S689F | Missense Mutation (SNP) | VAF 85/267 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1308451803; called by muse, mutect2, varscan2
- LILRA1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 104/326 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); catalogued as COSV52180971; called by muse, varscan2
- LMAN1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs772509644, COSV51828606; called by muse, mutect2, varscan2
- LRP1B | c.2149G>A p.D717N | Missense Mutation (SNP) | VAF 94/282 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as rs143197572; called by muse, mutect2, varscan2
- LRP2 | c.3964C>T p.H1322Y | Missense Mutation (SNP) | VAF 165/444 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV55544862; called by muse, mutect2, varscan2
- LRRIQ4 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 90/231 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61620442; called by muse, mutect2, varscan2
- LYG2 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60716275; called by muse, mutect2, varscan2
- MAGEC3 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs779268377; called by muse, mutect2, varscan2
- MAP3K13 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 13/475 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53990512; called by muse, mutect2
- MAP4K4 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 57/219 reads (26%) | catalogued as COSV56337027; called by muse, mutect2, varscan2
- MAT1A | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 111/342 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs200894913, COSV100944420; called by muse, mutect2, varscan2
- MCHR2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs770957970, COSV56000747; called by muse, mutect2, varscan2
- MCM3 | c.2150C>T p.P717L (on ENST00000229854 / NM_001366374.2; = p.P707L on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/359 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.381); catalogued as rs1010955185; called by muse, mutect2, varscan2
- MED12 | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 121/347 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as rs1365839691, COSV61347269; called by muse, mutect2, varscan2
- MEMO1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs775618103, COSV54451903; called by muse, mutect2, varscan2
- MME | c.185G>C p.C62S | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV64711977; called by muse, mutect2, varscan2
- MOSPD2 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs975603419; called by muse, mutect2, varscan2
- MRPS31 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 101/279 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60268515; called by muse, mutect2, varscan2
- MUC16 | c.33854C>T p.S11285F | Missense Mutation (SNP) | VAF 97/319 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.992); catalogued as rs781405689, COSV67444288; called by muse, mutect2, varscan2
- MUC16 | c.19538C>T p.S6513F | Missense Mutation (SNP) | VAF 86/283 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs1217887114, COSV67454232; called by muse, mutect2, varscan2
- MUC16 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.197); catalogued as rs769571404, COSV67446414; called by muse, mutect2, varscan2
- MUC5B | c.11098G>A p.A3700T | Missense Mutation (SNP) | VAF 189/598 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs761966007, COSV71589918; called by muse, mutect2, varscan2
- MYRFL | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 129/333 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs749853290; called by muse, mutect2, varscan2
- NAP1L2 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 98/370 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65172942; called by muse, mutect2, varscan2
- NELFE | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 167/686 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.033); catalogued as COSV64810571; called by muse, mutect2, varscan2
- NME8 | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.204); catalogued as COSV52252671; called by muse, mutect2, varscan2
- NPHP1 | c.1127C>T p.S376L (on ENST00000393272 / NM_207181.4; = p.S377L on NM_000272.5) | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.544); catalogued as rs1473660887; called by muse, mutect2, varscan2
- NPIPB11 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 123/261 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.95); catalogued as rs1219706462; called by muse, mutect2, varscan2
- NRG2 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 131/385 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866250848, COSV99179908; called by muse, mutect2, varscan2
- OPLAH | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 177/533 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.677); catalogued as rs782695188; called by muse, mutect2, varscan2
- OR10X1 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs764716071, COSV63767016; called by muse, mutect2, varscan2
- OR10X1 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 90/495 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63767431; called by muse, mutect2, varscan2
- OR14J1 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 194/412 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV65845669; called by mutect2, varscan2
- PARP1 | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 72/417 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779988758, COSV64689124; called by muse, mutect2, varscan2
- PDZD2 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 84/282 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.431); catalogued as rs778496147, COSV56864705; called by muse, mutect2, varscan2
- PKHD1L1 | c.7895C>T p.P2632L | Missense Mutation (SNP) | VAF 106/323 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770653367; called by muse, mutect2, varscan2
- PLA2G2E | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 92/386 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs762351431; called by muse, mutect2
- PLCB4 | c.1964-1G>A p.X655_splice | Splice Site (SNP) | VAF 68/212 reads (32%) | catalogued as COSV53804738; called by muse, mutect2, varscan2
- PLCB4 | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 90/263 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as COSV53820352; called by muse, mutect2, varscan2
- POLA1 | c.3298C>T p.L1100F | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs913112052, COSV66884411; called by muse, mutect2, varscan2
- PPIL4 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 126/259 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.368); catalogued as COSV53567282; called by muse, mutect2, varscan2
- PTPRT | c.2728G>A p.D910N | Missense Mutation (SNP) | VAF 71/258 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs761441812, COSV62012182; called by muse, mutect2, varscan2
- PTPRT | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 100/326 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV62005017; called by muse, mutect2, varscan2
- RAP1GAP | c.-112G>A | Splice Region (SNP) | VAF 76/248 reads (31%) | catalogued as COSV99265411; called by muse, mutect2, varscan2
- RBBP6 | c.3160C>T p.R1054* | Nonsense Mutation (SNP) | VAF 131/369 reads (36%) | catalogued as COSV60505227; called by muse, mutect2, varscan2
- RNASE3 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 99/380 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58959091; called by muse, mutect2, varscan2
- RP1 | c.4291G>A p.E1431K | Missense Mutation (SNP) | VAF 95/314 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55112914; called by muse, mutect2, varscan2
- RYR1 | c.7617C>T p.A2539= | Splice Region (SNP) | VAF 85/318 reads (27%) | catalogued as rs766619942; called by muse, mutect2, varscan2
- RYR3 | c.6710G>A p.G2237E | Missense Mutation (SNP) | VAF 392/557 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402878006, COSV63109402, COSV63109651; called by muse, mutect2, varscan2
- SCN11A | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 75/291 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV56569043; called by muse, mutect2, varscan2
- SCUBE1 | c.2146G>C p.G716R | Missense Mutation (SNP) | VAF 176/494 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.275); catalogued as COSV62614921; called by muse, mutect2, varscan2
- SELENOP | c.535-3C>T | Splice Region (SNP) | VAF 80/291 reads (27%) | catalogued as COSV100736912; called by muse, mutect2, varscan2
- SERPINB13 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 118/369 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs376580897; called by muse, mutect2, varscan2
- SLC26A9 | c.1501A>T p.N501Y | Missense Mutation (SNP) | VAF 110/339 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61600825; called by muse, mutect2, varscan2
- SLC36A4 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 78/238 reads (33%) | catalogued as COSV58397255; called by muse, mutect2, varscan2
- SLC38A4 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 160/439 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.052); catalogued as rs199895728, COSV56966903; called by muse, mutect2, varscan2
- SLFN14 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV70570314; called by muse, mutect2, varscan2
- SLIT2 | c.4108C>T p.R1370W | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs150261233, COSV56560396; called by muse, mutect2, varscan2
- SPEM1 | c.900T>A p.N300K | Missense Mutation (SNP) | VAF 97/218 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs1367983354; called by muse, mutect2, varscan2
- SPTBN4 | c.7235C>T p.P2412L | Missense Mutation (SNP) | VAF 195/581 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1236579821; called by muse, mutect2, varscan2
- ST6GAL2 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 66/221 reads (30%) | PolyPhen probably damaging (0.932); catalogued as rs138821621; called by muse, mutect2, varscan2
- STAB2 | c.6337G>A p.G2113R | Missense Mutation (SNP) | VAF 125/454 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388885909, COSV66348792; called by muse, mutect2, varscan2
- STOX2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 118/318 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs907510983; called by muse, varscan2
- SYCE1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 111/385 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1453700101, COSV58217911; called by muse, mutect2, varscan2
- SYDE1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 167/483 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1373568489; called by muse, varscan2
- TEK | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.807); catalogued as COSV101193633; called by muse, mutect2, varscan2
- TEX2 | c.2384C>T p.P795L (on ENST00000583097 / NM_001288733.2; = p.P802L on NM_018469.5) | Missense Mutation (SNP) | VAF 95/469 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as rs200257391, COSV51978469; called by muse, mutect2, varscan2
- TGFB3 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.073); catalogued as rs920721092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THSD4 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 467/651 reads (72%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.942); catalogued as COSV99965805; called by muse, mutect2, varscan2
- TP63 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 84/287 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.885); catalogued as rs754361670, COSV53209193, COSV53218266; called by muse, mutect2, varscan2
- TRIM24 | c.2581C>T p.P861S (on ENST00000343526 / NM_015905.3; = p.P827S on NM_003852.4) | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58971447; called by muse, mutect2, varscan2
- TTBK1 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 118/535 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52488097; called by muse, mutect2, varscan2
- TTN | c.33196G>A p.E11066K (on ENST00000591111; = p.E10139K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/427 reads (32%) | PolyPhen benign (0.053); catalogued as COSV60230256; called by muse, varscan2
- TTN | c.33091G>A p.E11031K (on ENST00000591111; = p.E10104K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/300 reads (37%) | PolyPhen benign (0.003); catalogued as COSV59922431; called by muse, varscan2
- UBTFL1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 88/147 reads (60%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.642); catalogued as rs759146588, COSV73297914; called by muse, mutect2, varscan2
- VCX | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 232/879 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.569); catalogued as COSV58233931; called by muse, mutect2, varscan2
- VSIR | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 142/425 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.361); catalogued as rs1001283730, COSV99824530; called by muse, mutect2, varscan2
- WASHC5 | c.2793T>A p.F931L | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV59195786; called by muse, mutect2, varscan2
- WDR59 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 182/540 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs759260011, COSV50939651; called by muse, mutect2, varscan2
- ZBTB40 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 94/300 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs993978885; called by muse, mutect2, varscan2
- ZFP92 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 233/592 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs782738099; called by muse, mutect2, varscan2
- ZNF174 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 115/405 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs141754530; called by muse, mutect2, varscan2
- ZNF862 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 143/444 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1320959342; called by muse, mutect2, varscan2
- ZNF98 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100757583; called by muse, mutect2, varscan2
- ZNF99 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 91/352 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs779186291; called by muse, mutect2, varscan2
- ABCG4 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 111/311 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- AC011462.1 | c.420C>A p.Y140* | Nonsense Mutation (SNP) | VAF 92/278 reads (33%) | called by muse, mutect2, varscan2
- ACSF3 | c.1715A>T p.H572L | Missense Mutation (SNP) | VAF 76/240 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); called by mutect2, varscan2
- ACSM6 | c.706G>C p.V236L | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ADGRF1 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 110/464 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADRA2A | c.1042C>G p.P348A | Missense Mutation (SNP) | VAF 163/498 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK | c.4426_4447del p.V1476Lfs*26 | Frame Shift Del (DEL) | VAF 90/387 reads (23%) | called by mutect2, pindel, varscan2
- AK9 | c.4631T>A p.L1544* | Nonsense Mutation (SNP) | VAF 62/130 reads (48%) | called by muse, mutect2
- ANK3 | c.6302C>T p.S2101F | Missense Mutation (SNP) | VAF 95/339 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ANKRD22 | c.234T>A p.H78Q | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APOBR | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 147/514 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- APOBR | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 145/512 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ARHGAP6 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 116/404 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARMCX2 | c.1756T>C p.F586L | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ASPM | c.4483C>G p.Q1495E | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASXL3 | c.3376G>A p.E1126K | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP11C | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 77/268 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL6B | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 101/197 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BIRC6 | c.3921G>T p.K1307N | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- C10orf71 | c.3992C>T p.P1331L | Missense Mutation (SNP) | VAF 161/432 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C11orf24 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 166/510 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C5AR2 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 159/470 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- C9orf40 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CALCR | c.505A>C p.I169L | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CCDC14 | c.586C>T p.P196S (on ENST00000488653; = p.P148S on NM_022757.5) | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC22 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 134/395 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCDC6 | c.328_330del p.E110del | In Frame Del (DEL) | VAF 52/178 reads (29%) | called by pindel, varscan2
- CD163 | c.2874G>A p.W958* | Nonsense Mutation (SNP) | VAF 99/337 reads (29%) | called by muse, mutect2, varscan2
- CD300E | c.590G>T p.R197M | Missense Mutation (SNP) | VAF 151/333 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC42EP1 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 173/490 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CDCA2 | c.1079T>G p.L360* | Nonsense Mutation (SNP) | VAF 78/264 reads (30%) | called by muse, mutect2, varscan2
- CDH26 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 82/292 reads (28%) | called by muse, mutect2, varscan2
- CELSR3 | c.7180C>T p.P2394S | Missense Mutation (SNP) | VAF 132/385 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPM | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- CEP350 | c.7227_7228del p.Q2410Vfs*5 | Frame Shift Del (DEL) | VAF 80/538 reads (15%) | called by pindel, varscan2
- CFHR5 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 84/539 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD5 | c.3517G>A p.V1173M | Missense Mutation (SNP) | VAF 114/419 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CMYA5 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 109/337 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CNTLN | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 110/313 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- COL9A3 | c.738G>A p.R246= | Splice Region (SNP) | VAF 106/365 reads (29%) | called by muse, mutect2, varscan2
- CSF2RB | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 195/621 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CXCL17 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- CYFIP2 | c.3464G>A p.W1155* (on ENST00000616178 / NM_001291722.2; = p.W1130* on NM_014376.4) | Nonsense Mutation (SNP) | VAF 101/298 reads (34%) | called by muse, mutect2, varscan2
- CYP4F11 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- DCAF4L2 | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 127/421 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- DCHS1 | c.3292C>T p.Q1098* | Nonsense Mutation (SNP) | VAF 149/430 reads (35%) | called by muse, mutect2, varscan2
- DDX25 | c.1105A>G p.S369G | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- DDX46 | c.2081A>T p.Y694F | Missense Mutation (SNP) | VAF 127/350 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- DEF8 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 139/443 reads (31%) | called by muse, mutect2, varscan2
- DHX15 | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 125/361 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DKK3 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 149/413 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DSCAML1 | c.5865G>A p.K1955= (on ENST00000321322; = p.K1895= on NM_020693.4) | Splice Region (SNP) | VAF 76/242 reads (31%) | called by muse, mutect2, varscan2
- DSTYK | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 231/442 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DYNC2H1 | c.4915A>G p.T1639A | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELOA3B | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 105/1144 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EPHB6 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 169/571 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ERN2 | c.2405C>T p.S802F | Missense Mutation (SNP) | VAF 115/300 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- FAM81A | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 405/558 reads (73%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT3 | c.1658G>A p.G553D | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FEZF1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 165/455 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FGGY | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 109/307 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- FLG | c.3533G>A p.G1178E | Missense Mutation (SNP) | VAF 181/504 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FLG2 | c.2510A>C p.E837A | Missense Mutation (SNP) | VAF 18/480 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2
- FLNB | c.2474T>G p.F825C | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FPR1 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 13/404 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.346); called by muse, mutect2
- FRMPD4 | c.2575G>A p.G859S | Missense Mutation (SNP) | VAF 152/446 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- FXR2 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 105/236 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- G6PC3 | c.806G>A p.C269Y | Missense Mutation (SNP) | VAF 27/664 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.025); called by muse, mutect2
- GOLGA8S | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by mutect2, varscan2
- GPATCH1 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 140/459 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); called by muse, mutect2
- GRIN1 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 122/379 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GRK4 | c.995G>A p.G332D (on ENST00000398052 / NM_182982.3; = p.G300D on NM_005307.3) | Missense Mutation (SNP) | VAF 108/312 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM5 | c.2747_2749delinsTG p.T916Mfs*110 (on ENST00000305447 / NM_001143831.2; = p.T884Mfs*110 on NM_000842.4) | Frame Shift Del (DEL) | VAF 56/254 reads (22%) | called by pindel, varscan2*
- GTF2I | c.239-1G>A p.X80_splice | Splice Site (SNP) | VAF 56/150 reads (37%) | called by muse, mutect2, varscan2
- HAO2 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 117/376 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- HCN1 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- HDX | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 117/427 reads (27%) | called by muse, mutect2, varscan2
- HGF | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 108/342 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- HOXA4 | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 117/311 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HSPG2 | c.10949T>G p.V3650G | Missense Mutation (SNP) | VAF 124/392 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2
- IL2RG | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 154/499 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- IMPG1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IRX5 | c.1136C>G p.A379G | Missense Mutation (SNP) | VAF 135/520 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2
- ITGB8 | c.1934A>C p.H645P | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- JAM2 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2
- KBTBD8 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 109/342 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KCNH3 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 126/411 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- KCNK13 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 87/297 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNQ5 | c.717C>G p.I239M | Missense Mutation (SNP) | VAF 112/230 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- KDM4F | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KDM5A | c.1801C>T p.H601Y | Missense Mutation (SNP) | VAF 93/276 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- KIDINS220 | c.3299C>T p.S1100F | Missense Mutation (SNP) | VAF 130/387 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- KIF1B | c.4019C>T p.S1340F (on ENST00000377086 / NM_001365952.1; = p.S1294F on NM_015074.3) | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KIF2B | c.1942A>C p.K648Q | Missense Mutation (SNP) | VAF 218/440 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); called by muse, mutect2
- KREMEN1 | c.1115C>T p.P372L (on ENST00000407188; = p.P374L on NM_032045.5) | Missense Mutation (SNP) | VAF 118/376 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT85 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 137/369 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KSR1 | c.1618G>A p.E540K (on ENST00000644974 / NM_001367810.1; = p.E425K on NM_014238.2) | Missense Mutation (SNP) | VAF 106/255 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- LAMC3 | c.4252G>A p.E1418K | Missense Mutation (SNP) | VAF 95/322 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LINC00514 | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- LINGO1 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 500/635 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- LMX1A | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 119/518 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRGUK | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LRRC53 | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- LRRC55 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 127/394 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- MAEL | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 115/281 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MAGEA1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.934); called by muse, mutect2
- MAP3K14 | c.2065C>T p.Q689* | Nonsense Mutation (SNP) | VAF 296/541 reads (55%) | called by muse, mutect2, varscan2
- MAP4K4 | c.2550_2551del p.H850Qfs*21 (on ENST00000347699 / NM_001242559.2; = p.H768Qfs*21 on NM_004834.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 54/207 reads (26%) | called by pindel, varscan2
- MAPK7 | c.1697_1698del p.R566Kfs*143 | Frame Shift Del (DEL) | VAF 126/338 reads (37%) | called by mutect2, pindel, varscan2
- MCPH1 | c.2285T>C p.M762T | Missense Mutation (SNP) | VAF 104/409 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- MEI4 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- MGAM2 | c.4216T>G p.S1406A | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MIB2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 82/247 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIOX | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 146/497 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MPST | c.589C>T p.R197* (on ENST00000341116 / NM_001369904.2; = p.R217* on NM_021126.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 81/303 reads (27%) | called by muse, mutect2, varscan2
- MRPL49 | c.449A>C p.K150T | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- MSL3 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MUC22 | c.4457A>G p.N1486S | Missense Mutation (SNP) | VAF 220/456 reads (48%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.461); called by muse, varscan2
- MXRA5 | c.7448G>A p.G2483D | Missense Mutation (SNP) | VAF 162/453 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYBBP1A | c.3878C>T p.S1293F | Missense Mutation (SNP) | VAF 100/373 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- NAV2 | c.1303G>A p.G435R (on ENST00000396087 / NM_001244963.2; = p.G412R on NM_145117.5) | Missense Mutation (SNP) | VAF 141/470 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV2 | c.1304G>A p.G435E (on ENST00000396087 / NM_001244963.2; = p.G412E on NM_145117.5) | Missense Mutation (SNP) | VAF 141/470 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEFM | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 106/412 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- NEK2 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 84/362 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP10 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 170/507 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- NLRP2 | c.327G>A p.G109= | Splice Region (SNP) | VAF 125/364 reads (34%) | called by muse, mutect2, varscan2
- NPAP1 | c.2506T>A p.L836M | Missense Mutation (SNP) | VAF 79/435 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- NPAS3 | c.2344A>T p.N782Y (on ENST00000356141 / NM_001164749.2; = p.N750Y on NM_022123.3) | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); called by muse, mutect2
- NUP155 | c.3173C>T p.P1058L (on ENST00000231498 / NM_153485.3; = p.P999L on NM_004298.4) | Missense Mutation (SNP) | VAF 88/267 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- NUP210L | c.4249G>A p.G1417R | Missense Mutation (SNP) | VAF 97/552 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- OBSCN | c.2282G>C p.R761P | Missense Mutation (SNP) | VAF 183/902 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); called by muse, mutect2
- OR4C16 | c.737T>G p.I246S | Missense Mutation (SNP) | VAF 132/471 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- OR4K17 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 65/370 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACS2 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PAPPA | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 151/437 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- PCDHGA9 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 110/312 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PCSK1 | c.1803G>A p.M601I | Missense Mutation (SNP) | VAF 134/404 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- PDCL | c.892C>G p.L298V | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHEX | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PIK3CB | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PLA2G5 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 105/267 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PLEKHG6 | c.1721_1722del p.T574Rfs*2 | Frame Shift Del (DEL) | VAF 71/296 reads (24%) | called by pindel, varscan2
- PLXNB2 | c.3341C>T p.A1114V | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PPBP | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- PRR33 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 153/453 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMD8 | c.560dup p.Y187* | Nonsense Mutation (INS) | VAF 100/347 reads (29%) | called by mutect2, pindel, varscan2
- PTPN14 | c.1828C>T p.Q610* | Nonsense Mutation (SNP) | VAF 302/810 reads (37%) | called by muse, mutect2, varscan2
- PTPRG | c.912T>A p.N304K | Missense Mutation (SNP) | VAF 57/376 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- R3HDM1 | c.2474C>T p.P825L | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- RBM12B | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RERE | c.3326C>T p.P1109L | Missense Mutation (SNP) | VAF 177/555 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- RERG | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RHEB | c.242A>C p.Y81S | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMBP3 | c.4339G>A p.G1447R | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.133); called by mutect2, varscan2
- RMND5A | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- RP1 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SAP25 | c.299C>T p.S100F (on ENST00000538735; = p.S198F on NM_001168682.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/337 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SCAF1 | c.3744C>A p.H1248Q | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCML1 | c.916G>A p.V306M (on ENST00000380041 / NM_001037540.3; = p.V279M on NM_006746.6) | Missense Mutation (SNP) | VAF 91/289 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SCN10A | c.5510C>T p.S1837L | Missense Mutation (SNP) | VAF 108/318 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SCN2B | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 108/359 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEPTIN6 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 105/370 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SERPINA7 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 177/518 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- SGCD | c.425C>T p.T142I (on ENST00000435422 / NM_001128209.2; = p.T143I on NM_000337.5) | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- SHISA7 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 124/320 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SLAMF8 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 97/482 reads (20%) | called by muse, mutect2, varscan2
- SLC16A9 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- SLC2A3 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC35F3 | c.1067G>A p.G356E (on ENST00000366617 / NM_001300845.1; = p.G425E on NM_173508.4) | Missense Mutation (SNP) | VAF 93/547 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC38A1 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 80/257 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC38A10 | c.1644_1645del p.K549Tfs*23 | Frame Shift Del (DEL) | VAF 256/678 reads (38%) | called by pindel, varscan2
- SLC38A3 | c.1118T>C p.V373A | Missense Mutation (SNP) | VAF 141/409 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- SLC5A12 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 128/372 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SMCHD1 | c.5324C>T p.P1775L | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- SMIM31 | c.85T>C p.Y29H | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- SOGA1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 127/340 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SPATA31A1 | c.2749G>A p.G917R | Missense Mutation (SNP) | VAF 65/366 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SPHK1 | c.1046C>T p.A349V (on ENST00000392496 / NM_001355139.2; = p.A363V on NM_021972.4) | Missense Mutation (SNP) | VAF 233/483 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SSC5D | c.2009_2010del p.T670Rfs*9 | Frame Shift Del (DEL) | VAF 102/478 reads (21%) | called by mutect2, pindel, varscan2
- SSR1 | c.578_579del p.T193Sfs*5 | Frame Shift Del (DEL) | VAF 64/370 reads (17%) | called by mutect2, pindel, varscan2
- STK10 | c.2237T>C p.M746T | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STK3 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 100/293 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STOX2 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SYT16 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYTL5 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 104/320 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TBC1D15 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 141/432 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCHH | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 120/478 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- TG | c.6182G>A p.G2061E | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TOP3B | c.911_912del p.V304Gfs*22 | Frame Shift Del (DEL) | VAF 80/308 reads (26%) | called by pindel, varscan2
- TRAPPC9 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 139/421 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2
- TRIL | c.152A>G p.K51R | Missense Mutation (SNP) | VAF 149/380 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- TRIM65 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 91/341 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIO | c.748T>G p.L250V | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TRMT44 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPV5 | c.1436C>A p.T479N | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- TTC34 | c.1370G>A p.C457Y | Missense Mutation (SNP) | VAF 153/469 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- TTN | c.86645C>T p.P28882L (on ENST00000591111; = p.P21458L on NM_003319.4) | Missense Mutation (SNP) | VAF 59/209 reads (28%) | PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TTN | c.12398C>T p.S4133F (on ENST00000591111; = p.S4087F on NM_003319.4) | Missense Mutation (SNP) | VAF 122/357 reads (34%) | called by muse, mutect2, varscan2
- U2SURP | c.1564_1565del p.E522Sfs*7 | Frame Shift Del (DEL) | VAF 87/306 reads (28%) | called by mutect2, pindel, varscan2
- UNC45B | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 163/403 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNKL | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 158/443 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP11 | c.2613A>T p.K871N (on ENST00000218348; = p.K828N on NM_001371072.1) | Missense Mutation (SNP) | VAF 141/410 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- VARS2 | c.2906C>T p.S969F | Missense Mutation (SNP) | VAF 259/569 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, varscan2
- VAX2 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 134/406 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VCPKMT | c.502T>G p.C168G | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- WASF1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ZDHHC15 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF275 | c.188A>T p.E63V | Missense Mutation (SNP) | VAF 153/448 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZNF595 | c.1381T>C p.F461L | Missense Mutation (SNP) | VAF 119/345 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ABCA12 | c.132G>A p.R44= | Silent (SNP) | VAF 61/186 reads (33%) | called by muse, mutect2, varscan2
- ACSM1 | c.1002C>T p.F334= | Silent (SNP) | VAF 76/260 reads (29%) | catalogued as COSV54639996; called by muse, mutect2
- ACTC1 | c.99C>T p.F33= | Silent (SNP) | VAF 310/419 reads (74%) | catalogued as rs763616452, COSV51758609, COSV51758716; called by muse, mutect2, varscan2
- ADAM19 | c.2556C>T p.F852= | Silent (SNP) | VAF 96/267 reads (36%) | called by muse, mutect2, varscan2
- ADAM20 | c.393C>T p.G131= | Silent (SNP) | VAF 110/279 reads (39%) | called by muse, mutect2, varscan2
- ADCY4 | c.1863C>T p.L621= | Silent (SNP) | VAF 113/362 reads (31%) | catalogued as rs145940354; called by muse, mutect2, varscan2
- ADGRB3 | c.1935C>T p.F645= | Silent (SNP) | VAF 64/169 reads (38%) | catalogued as COSV65394003; called by muse, mutect2, varscan2
- AGAP5 | c.1956C>T p.A652= | Silent (SNP) | VAF 140/538 reads (26%) | called by muse, mutect2, varscan2
- AMER1 | c.582C>T p.A194= | Silent (SNP) | VAF 193/495 reads (39%) | called by muse, mutect2, varscan2
- AMPD2 | c.1581C>T p.Y527= | Silent (SNP) | VAF 69/201 reads (34%) | called by muse, mutect2, varscan2
- ANTXR1 | c.1623C>T p.P541= | Silent (SNP) | VAF 95/253 reads (38%) | catalogued as rs1229945471, COSV58019931; called by muse, mutect2, varscan2
- AP5Z1 | c.1179C>T p.F393= | Silent (SNP) | VAF 122/380 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP45 | c.1605C>T p.D535= | Silent (SNP) | VAF 148/392 reads (38%) | called by muse, mutect2, varscan2
- ASPM | c.6309T>A p.V2103= | Silent (SNP) | VAF 93/450 reads (21%) | called by muse, mutect2, varscan2
- BCL6 | c.882C>T p.F294= | Silent (SNP) | VAF 136/418 reads (33%) | catalogued as COSV51651724, COSV51651738; called by muse, mutect2, varscan2
- BOD1L2 | c.474G>A p.E158= | Silent (SNP) | VAF 68/218 reads (31%) | catalogued as COSV73996953; called by muse, mutect2, varscan2
- BPIFA2 | c.693C>T p.V231= | Silent (SNP) | VAF 110/328 reads (34%) | catalogued as rs1304627544, COSV53612534; called by muse, mutect2, varscan2
- C7orf57 | c.163C>T p.L55= | Silent (SNP) | VAF 116/347 reads (33%) | catalogued as rs769546871, COSV62363175; called by muse, mutect2, varscan2
- CA5B | c.813G>A p.G271= | Silent (SNP) | VAF 101/414 reads (24%) | called by muse, mutect2, varscan2
- CCR1 | c.534C>T p.F178= | Silent (SNP) | VAF 132/347 reads (38%) | called by muse, mutect2, varscan2
- CD33 | c.114C>T p.L38= | Silent (SNP) | VAF 121/344 reads (35%) | catalogued as rs1427538478; called by muse, mutect2, varscan2
- CDKN2A | c.171C>T p.A57= | Silent (SNP) | VAF 135/409 reads (33%) | catalogued as rs876658199, COSV58687724, COSV58705214; ClinVar: likely benign; called by muse, mutect2, varscan2
- CERS1 | c.294G>A p.K98= | Silent (SNP) | VAF 125/388 reads (32%) | catalogued as rs186889230; called by muse, mutect2, varscan2
- CHD5 | c.3516G>C p.V1172= | Silent (SNP) | VAF 115/422 reads (27%) | called by muse, mutect2, varscan2
- COG1 | c.2790C>T p.I930= | Silent (SNP) | VAF 90/359 reads (25%) | catalogued as rs770966526, COSV55429036; called by muse, mutect2, varscan2
- COL5A1 | c.4527G>A p.Q1509= | Silent (SNP) | VAF 121/333 reads (36%) | called by muse, mutect2, varscan2
- CRX | c.406C>T p.L136= | Silent (SNP) | VAF 134/437 reads (31%) | catalogued as rs937907656; called by muse, mutect2, varscan2
- CTNND2 | c.195G>T p.L65= | Silent (SNP) | VAF 77/249 reads (31%) | called by muse, mutect2, varscan2
- CYP4F3 | c.153C>T p.F51= | Silent (SNP) | VAF 88/274 reads (32%) | catalogued as rs1007946585; called by muse, mutect2, varscan2
- DCDC1 | c.4173G>A p.R1391= (on ENST00000597505 / NM_001367979.1; = p.R498= on NM_020869.3) | Silent (SNP) | VAF 127/411 reads (31%) | called by muse, mutect2, varscan2
- DCLK3 | c.1725C>T p.L575= | Silent (SNP) | VAF 73/269 reads (27%) | catalogued as COSV69362394; called by muse, mutect2, varscan2
- DHRS7B | c.966C>T p.S322= | Silent (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- DHX37 | c.1167C>T p.S389= | Silent (SNP) | VAF 93/287 reads (32%) | catalogued as rs1260888090; called by muse, mutect2, varscan2
- DNAH1 | c.1533G>A p.T511= | Silent (SNP) | VAF 99/287 reads (34%) | catalogued as rs774468676; called by muse, mutect2, varscan2
- DNAH7 | c.10584C>T p.F3528= | Silent (SNP) | VAF 121/374 reads (32%) | catalogued as COSV56765990; called by muse, mutect2, varscan2
- DNER | c.1119G>A p.G373= | Silent (SNP) | VAF 98/289 reads (34%) | called by muse, mutect2, varscan2
- DSTYK | c.1572C>T p.A524= | Silent (SNP) | VAF 233/446 reads (52%) | catalogued as rs1192347039; called by muse, mutect2, varscan2
- ECE1 | c.2092C>T p.L698= | Silent (SNP) | VAF 104/398 reads (26%) | catalogued as COSV99942103; called by muse, mutect2, varscan2
- EDRF1 | c.3009C>T p.S1003= (on ENST00000356792 / NM_001202438.2; = p.S969= on NM_015608.2) | Silent (SNP) | VAF 100/282 reads (35%) | called by muse, mutect2, varscan2
- ELOA3C | c.672C>T p.P224= | Silent (SNP) | VAF 138/1745 reads (8%) | called by muse, mutect2
- ERC2 | c.2196C>T p.I732= | Silent (SNP) | VAF 80/242 reads (33%) | catalogued as rs1207007057, COSV55597231; called by muse, mutect2, varscan2
- ERICH3 | c.1059C>T p.F353= | Silent (SNP) | VAF 119/334 reads (36%) | catalogued as rs769875646, COSV58607407; called by muse, mutect2, varscan2
- FAM186A | c.2859G>A p.A953= | Silent (SNP) | VAF 157/472 reads (33%) | catalogued as rs566857221, COSV59248552; called by muse, mutect2, varscan2
- FAM71A | c.234C>T p.P78= | Silent (SNP) | VAF 282/724 reads (39%) | called by muse, mutect2, varscan2
- FAT3 | c.4200G>A p.G1400= | Silent (SNP) | VAF 75/212 reads (35%) | catalogued as COSV99970405; called by muse, mutect2, varscan2
- FER1L6 | c.285G>A p.L95= | Silent (SNP) | VAF 103/298 reads (35%) | catalogued as rs555591938; called by muse, mutect2, varscan2
- FGD4 | c.558C>T p.S186= | Silent (SNP) | VAF 82/281 reads (29%) | catalogued as rs1401402795; called by muse, varscan2
- FLII | c.822G>A p.L274= | Silent (SNP) | VAF 66/302 reads (22%) | called by muse, mutect2, varscan2
- GLYATL2 | c.225C>T p.Y75= | Silent (SNP) | VAF 70/239 reads (29%) | catalogued as rs754224500, COSV54851709; called by muse, mutect2, varscan2
- GPR101 | c.1305G>A p.V435= | Silent (SNP) | VAF 160/490 reads (33%) | catalogued as rs865948649; called by muse, mutect2, varscan2
- GRIA2 | c.1863T>A p.I621= | Silent (SNP) | VAF 83/263 reads (32%) | called by muse, mutect2, varscan2
- GRIN2B | c.3777C>T p.S1259= | Silent (SNP) | VAF 132/397 reads (33%) | catalogued as rs201872316; called by muse, mutect2, varscan2
- H6PD | c.2085C>T p.A695= | Silent (SNP) | VAF 161/461 reads (35%) | catalogued as rs369746502, COSV66230139; called by muse, mutect2, varscan2
- HCCS | c.759G>A p.S253= | Silent (SNP) | VAF 123/425 reads (29%) | catalogued as rs34228583, COSV100335753, COSV58239614; called by muse, mutect2, varscan2
- HORMAD2 | c.267T>C p.G89= | Silent (SNP) | VAF 91/253 reads (36%) | called by muse, mutect2, varscan2
- HS1BP3 | c.129C>T p.I43= | Silent (SNP) | VAF 141/442 reads (32%) | called by muse, mutect2, varscan2
- HSPG2 | c.10950C>G p.V3650= | Silent (SNP) | VAF 121/387 reads (31%) | called by muse, mutect2
- HYDIN | c.4233G>A p.T1411= | Silent (SNP) | VAF 52/188 reads (28%) | catalogued as rs867406528, COSV101142048; called by muse, mutect2, varscan2
- IFNLR1 | c.687C>T p.F229= | Silent (SNP) | VAF 82/266 reads (31%) | called by muse, mutect2, varscan2
- KCNC2 | c.1164C>T p.F388= | Silent (SNP) | VAF 94/292 reads (32%) | catalogued as rs972000837, COSV54367557; called by muse, mutect2, varscan2
- KDM4F | c.1401G>A p.G467= | Silent (SNP) | VAF 86/253 reads (34%) | called by muse, mutect2, varscan2
- KIF26A | c.5259C>T p.I1753= | Silent (SNP) | VAF 181/523 reads (35%) | catalogued as rs535957728; called by muse, mutect2, varscan2
- KLK8 | c.309C>T p.S103= | Silent (SNP) | VAF 121/431 reads (28%) | called by muse, mutect2, varscan2
- KMT2A | c.5298T>C p.F1766= | Silent (SNP) | VAF 70/230 reads (30%) | called by muse, mutect2, varscan2
- KRT26 | c.663C>T p.L221= | Silent (SNP) | VAF 149/312 reads (48%) | called by muse, mutect2, varscan2
- LAMA5 | c.4557C>T p.C1519= | Silent (SNP) | VAF 142/415 reads (34%) | catalogued as rs1568932181; called by muse, mutect2, varscan2
- LOXHD1 | c.6522C>T p.V2174= (on ENST00000642948; = p.V2112= on NM_144612.7) | Silent (SNP) | VAF 135/413 reads (33%) | catalogued as COSV56069975; called by muse, mutect2, varscan2
- LRRC38 | c.795C>T p.S265= | Silent (SNP) | VAF 118/398 reads (30%) | called by muse, mutect2, varscan2
- MACROH2A1 | c.924C>T p.S308= (on ENST00000510038; = p.S307= on NM_004893.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/242 reads (33%) | called by muse, mutect2, varscan2
- MAML2 | c.2160C>A p.G720= | Silent (SNP) | VAF 79/244 reads (32%) | called by muse, mutect2, varscan2
- MCEMP1 | c.312C>T p.I104= | Silent (SNP) | VAF 94/283 reads (33%) | called by muse, varscan2
- MGAM | c.5331G>A p.T1777= | Silent (SNP) | VAF 80/216 reads (37%) | catalogued as rs374695000, COSV101527600; called by muse, mutect2, varscan2
- MIA3 | c.306C>T p.I102= | Silent (SNP) | VAF 161/289 reads (56%) | called by muse, mutect2, varscan2
- MINDY2 | c.1335G>A p.R445= | Silent (SNP) | VAF 176/235 reads (75%) | called by muse, mutect2, varscan2
- MPO | c.1491C>T p.A497= | Silent (SNP) | VAF 114/568 reads (20%) | called by muse, mutect2, varscan2
- MRC2 | c.4155C>T p.T1385= | Silent (SNP) | VAF 213/411 reads (52%) | catalogued as COSV57636783; called by muse, mutect2, varscan2
- MTUS2 | c.517A>C p.R173= | Silent (SNP) | VAF 104/323 reads (32%) | called by muse, mutect2, varscan2
- MUC16 | c.17085G>A p.Q5695= | Silent (SNP) | VAF 182/525 reads (35%) | called by muse, mutect2
- MYCBPAP | c.267C>T p.I89= | Silent (SNP) | VAF 88/410 reads (21%) | called by muse, mutect2, varscan2
- MYH2 | c.4740G>A p.R1580= | Silent (SNP) | VAF 89/185 reads (48%) | catalogued as COSV55431125; called by muse, mutect2, varscan2
- MYH8 | c.3375C>T p.I1125= | Silent (SNP) | VAF 112/226 reads (50%) | catalogued as COSV67961904, COSV67967038; called by muse, mutect2, varscan2
- MYO3B | c.3135C>T p.L1045= | Silent (SNP) | VAF 63/193 reads (33%) | catalogued as rs752825996, COSV58694396; called by muse, mutect2, varscan2
- MYRFL | c.2706C>T p.F902= | Silent (SNP) | VAF 76/264 reads (29%) | called by muse, mutect2, varscan2
- NOC4L | c.138C>T p.I46= | Silent (SNP) | VAF 107/309 reads (35%) | catalogued as rs1055869650; called by muse, mutect2, varscan2
- NOVA1 | c.1137G>A p.T379= | Silent (SNP) | VAF 110/345 reads (32%) | catalogued as rs144344947, COSV57478512; called by muse, varscan2
- NPY5R | c.1242C>T p.G414= | Silent (SNP) | VAF 87/287 reads (30%) | called by muse, mutect2, varscan2
- NUP210 | c.1023C>T p.Y341= | Silent (SNP) | VAF 79/323 reads (24%) | catalogued as rs775614047, COSV54405917; called by muse, mutect2, varscan2
- OASL | c.432G>A p.G144= | Silent (SNP) | VAF 114/362 reads (31%) | catalogued as rs150665123; called by muse, mutect2, varscan2
- OGDH | c.336C>T p.S112= | Silent (SNP) | VAF 115/379 reads (30%) | called by muse, mutect2, varscan2
- OR2AT4 | c.705C>T p.S235= | Silent (SNP) | VAF 111/351 reads (32%) | catalogued as rs886472269; called by muse, mutect2, varscan2
- OR2M3 | c.42C>T p.L14= | Silent (SNP) | VAF 107/593 reads (18%) | catalogued as COSV71759157; called by muse, mutect2, varscan2
- OR4E1 | c.651C>T p.V217= | Silent (SNP) | VAF 70/198 reads (35%) | called by muse, mutect2, varscan2
- OR51F2 | c.669C>T p.I223= | Silent (SNP) | VAF 110/317 reads (35%) | catalogued as rs753314255, COSV59065815; called by muse, mutect2, varscan2
- OR51V1 | c.669G>T p.L223= | Silent (SNP) | VAF 122/340 reads (36%) | called by muse, mutect2, varscan2
- OR52N4 | c.303C>G p.V101= | Silent (SNP) | VAF 98/355 reads (28%) | called by muse, mutect2, varscan2
- OR5AR1 | c.744C>T p.I248= | Silent (SNP) | VAF 105/319 reads (33%) | catalogued as COSV57254013; called by muse, mutect2, varscan2
- OR5C1 | c.675C>T p.I225= | Silent (SNP) | VAF 133/393 reads (34%) | catalogued as rs762811453, COSV65456169; called by muse, mutect2, varscan2
- OR6Y1 | c.774C>T p.S258= | Silent (SNP) | VAF 112/548 reads (20%) | catalogued as rs1487119081, COSV56929323; called by muse, mutect2
- OR7C2 | c.405C>T p.I135= | Silent (SNP) | VAF 143/404 reads (35%) | called by muse, mutect2, varscan2
- OR8U1 | c.207G>A p.V69= | Silent (SNP) | VAF 129/458 reads (28%) | catalogued as rs759212931, COSV56416921; called by muse, varscan2
- PAPPA | c.2469G>A p.G823= | Silent (SNP) | VAF 143/412 reads (35%) | catalogued as rs760421246, COSV60291538; called by muse, mutect2, varscan2
- PATJ | c.4158A>C p.P1386= | Silent (SNP) | VAF 70/261 reads (27%) | called by muse, mutect2, varscan2
- PAX7 | c.129G>A p.G43= | Silent (SNP) | VAF 125/402 reads (31%) | called by muse, mutect2, varscan2
- PCDH18 | c.1308C>T p.I436= | Silent (SNP) | VAF 119/353 reads (34%) | catalogued as rs746607893, COSV61267669; called by muse, mutect2, varscan2
- PCDHGA2 | c.1377C>T p.T459= | Silent (SNP) | VAF 138/428 reads (32%) | catalogued as rs151215678, COSV54055296; called by muse, mutect2, varscan2
- PCLO | c.10599C>T p.T3533= | Silent (SNP) | VAF 121/365 reads (33%) | catalogued as rs780621377, COSV61655566; called by muse, mutect2, varscan2
- PDZD2 | c.3273C>T p.V1091= | Silent (SNP) | VAF 115/349 reads (33%) | called by muse, mutect2, varscan2
- PIGO | c.2196C>T p.L732= | Silent (SNP) | VAF 162/456 reads (36%) | catalogued as rs779088175; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLAU | c.1278G>A p.E426= | Silent (SNP) | VAF 109/323 reads (34%) | called by muse, mutect2, varscan2
- PLCZ1 | c.120G>A p.V40= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as COSV56848899; called by muse, mutect2, varscan2
- PLEKHG3 | c.745C>T p.L249= (on ENST00000394691; = p.L305= on NM_001308147.2) | Silent (SNP) | VAF 145/409 reads (35%) | called by muse, mutect2, varscan2
- PLXNA1 | c.4074C>T p.F1358= | Silent (SNP) | VAF 123/332 reads (37%) | catalogued as rs1260451040; called by muse, mutect2, varscan2
- PLXNC1 | c.3624C>T p.I1208= | Silent (SNP) | VAF 74/266 reads (28%) | catalogued as COSV51576993; called by muse, mutect2, varscan2
- POTEF | c.3114C>T p.S1038= | Silent (SNP) | VAF 76/442 reads (17%) | catalogued as rs1226771285; called by muse, mutect2, varscan2
- PRDM9 | c.459C>T p.S153= | Silent (SNP) | VAF 110/335 reads (33%) | catalogued as rs1302013225; called by muse, mutect2, varscan2
- PRF1 | c.1305G>A p.T435= | Silent (SNP) | VAF 128/462 reads (28%) | catalogued as rs200167080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PROKR2 | c.312C>T p.I104= | Silent (SNP) | VAF 138/364 reads (38%) | called by muse, mutect2, varscan2
- PRRC2C | c.4503T>C p.A1501= (on ENST00000367742; = p.A1499= on NM_015172.4) | Silent (SNP) | VAF 92/477 reads (19%) | called by muse, mutect2, varscan2
- PTBP1 | c.1224C>T p.L408= (on ENST00000349038 / NM_031991.4; = p.L434= on NM_002819.5) | Silent (SNP) | VAF 155/403 reads (38%) | called by muse, mutect2, varscan2
- PTK7 | c.237C>T p.F79= | Silent (SNP) | VAF 166/670 reads (25%) | catalogued as rs370691630; called by muse, mutect2, varscan2
- PTPN3 | c.273C>T p.I91= | Silent (SNP) | VAF 81/274 reads (30%) | called by muse, mutect2, varscan2
- PTPRB | c.4698C>T p.F1566= | Silent (SNP) | VAF 67/234 reads (29%) | called by muse, mutect2, varscan2
- PTPRR | c.438C>T p.L146= | Silent (SNP) | VAF 95/288 reads (33%) | catalogued as rs753094547, COSV51742265; called by muse, mutect2, varscan2
- RGS9 | c.1506C>T p.S502= | Silent (SNP) | VAF 357/704 reads (51%) | called by muse, mutect2, varscan2
- RHNO1 | c.456C>T p.F152= | Silent (SNP) | VAF 92/334 reads (28%) | called by muse, mutect2
- RNASE3 | c.324C>T p.L108= | Silent (SNP) | VAF 101/384 reads (26%) | catalogued as COSV58959541; called by muse, mutect2, varscan2
- SCN11A | c.5002C>T p.L1668= | Silent (SNP) | VAF 117/387 reads (30%) | catalogued as COSV56570457; called by muse, mutect2, varscan2
- SCN4A | c.594C>T p.F198= | Silent (SNP) | VAF 73/353 reads (21%) | called by muse, mutect2, varscan2
- SEMA3D | c.993C>T p.L331= | Silent (SNP) | VAF 34/182 reads (19%) | catalogued as COSV52393585; called by muse, mutect2, varscan2
- SERPINA1 | c.150C>T p.I50= | Silent (SNP) | VAF 165/600 reads (28%) | called by muse, mutect2, varscan2
- SGSM1 | c.1014G>A p.V338= | Silent (SNP) | VAF 116/386 reads (30%) | called by muse, mutect2, varscan2
- SGSM1 | c.2013G>A p.R671= | Silent (SNP) | VAF 141/418 reads (34%) | called by muse, mutect2, varscan2
- SHANK3 | c.3948C>G p.L1316= | Silent (SNP) | VAF 148/517 reads (29%) | called by muse, mutect2, varscan2
- SLC12A3 | c.669C>T p.F223= | Silent (SNP) | VAF 131/436 reads (30%) | catalogued as rs779986569, COSV52633150; called by muse, mutect2, varscan2
- SLC26A9 | c.1500A>T p.R500= | Silent (SNP) | VAF 109/335 reads (33%) | called by muse, mutect2, varscan2
- SLC35F4 | c.1125C>T p.I375= (on ENST00000339762 / NM_001352015.2; = p.I339= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/403 reads (17%) | catalogued as COSV60264531; called by muse, mutect2, varscan2
- SLC39A8 | c.1170C>T p.F390= | Silent (SNP) | VAF 113/333 reads (34%) | catalogued as rs143526887; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A3 | c.324C>A p.L108= | Silent (SNP) | VAF 87/274 reads (32%) | catalogued as rs1569467758, COSV53226992; called by muse, mutect2, varscan2
- SPATA31A1 | c.2023C>T p.L675= | Silent (SNP) | VAF 188/875 reads (21%) | catalogued as rs1186376703; called by muse, mutect2, varscan2
- SPATC1 | c.525G>A p.V175= | Silent (SNP) | VAF 167/519 reads (32%) | catalogued as COSV66299515; called by muse, mutect2, varscan2
- SPHK1 | c.1047C>T p.A349= (on ENST00000392496 / NM_001355139.2; = p.A363= on NM_021972.4) | Silent (SNP) | VAF 234/482 reads (49%) | catalogued as rs148346259; called by muse, mutect2, varscan2
- SRD5A2 | c.669C>T p.F223= | Silent (SNP) | VAF 75/284 reads (26%) | catalogued as COSV51870524; called by muse, mutect2, varscan2
- STAC2 | c.1089C>T p.S363= | Silent (SNP) | VAF 113/415 reads (27%) | catalogued as rs759722603; called by muse, mutect2, varscan2
- STXBP1 | c.933T>A p.S311= | Silent (SNP) | VAF 67/262 reads (26%) | called by muse, mutect2, varscan2
- SVEP1 | c.141C>T p.P47= | Silent (SNP) | VAF 180/491 reads (37%) | called by muse, mutect2, varscan2
- SYDE1 | c.597C>T p.S199= | Silent (SNP) | VAF 177/506 reads (35%) | catalogued as rs1232556940, COSV61442476; called by muse, mutect2, varscan2
- SYTL5 | c.1267C>T p.L423= | Silent (SNP) | VAF 116/404 reads (29%) | called by muse, mutect2, varscan2
- TBC1D22A | c.1440C>T p.F480= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as COSV61439441; called by muse, mutect2, varscan2
- TEKT1 | c.1155C>T p.I385= | Silent (SNP) | VAF 86/198 reads (43%) | catalogued as rs199826606; called by muse, mutect2, varscan2
- TENM3 | c.7869G>A p.Q2623= | Silent (SNP) | VAF 149/340 reads (44%) | catalogued as COSV69312878; called by muse, mutect2, varscan2
- TEX2 | c.2385C>T p.P795= (on ENST00000583097 / NM_001288733.2; = p.P802= on NM_018469.5) | Silent (SNP) | VAF 94/461 reads (20%) | catalogued as rs201414066; called by muse, mutect2, varscan2
- TFRC | c.222C>T p.I74= | Silent (SNP) | VAF 77/199 reads (39%) | catalogued as rs745734170, COSV64056140; called by muse, mutect2, varscan2
- TMC5 | c.1122G>A p.R374= (on ENST00000396229 / NM_001105248.1; = p.R128= on NM_024780.5) | Silent (SNP) | VAF 80/238 reads (34%) | catalogued as rs1265394185, COSV54902669; called by muse, mutect2, varscan2
- TP63 | c.336G>A p.T112= | Silent (SNP) | VAF 72/224 reads (32%) | catalogued as rs267599728, COSV53196338; called by muse, mutect2, varscan2
- TRIM54 | c.298C>T p.L100= | Silent (SNP) | VAF 90/330 reads (27%) | catalogued as rs765136438; called by muse, mutect2, varscan2
- TRIO | c.5535C>T p.S1845= | Silent (SNP) | VAF 125/385 reads (32%) | called by muse, mutect2, varscan2
- TRPC3 | c.975G>A p.E325= (on ENST00000379645 / NM_001366479.2; = p.E252= on NM_003305.2) | Silent (SNP) | VAF 48/197 reads (24%) | catalogued as COSV99312727; called by muse, mutect2, varscan2
- TSNARE1 | c.537C>T p.R179= | Silent (SNP) | VAF 147/447 reads (33%) | catalogued as rs760178331, COSV56173011; called by muse, mutect2, varscan2
- TSPAN33 | c.744C>T p.I248= | Silent (SNP) | VAF 55/170 reads (32%) | catalogued as COSV99179751; called by muse, mutect2, varscan2
- TTN | c.39171C>T p.I13057= (on ENST00000591111; = p.I5633= on NM_003319.4) | Silent (SNP) | VAF 86/295 reads (29%) | catalogued as COSV60067040, COSV60381602; called by muse, mutect2, varscan2
- UGT2A3 | c.1110C>T p.I370= | Silent (SNP) | VAF 101/293 reads (34%) | called by muse, mutect2, varscan2
- UGT3A1 | c.1182G>A p.Q394= | Silent (SNP) | VAF 154/466 reads (33%) | called by muse, mutect2, varscan2
- VARS1 | c.1599G>A p.V533= | Silent (SNP) | VAF 143/677 reads (21%) | called by muse, mutect2, varscan2
- VARS2 | c.2907C>T p.S969= | Silent (SNP) | VAF 286/607 reads (47%) | catalogued as rs763079766; called by muse, mutect2, varscan2
- VSIG4 | c.720G>A p.K240= | Silent (SNP) | VAF 102/369 reads (28%) | called by muse, mutect2, varscan2
- WNK2 | c.3714C>T p.I1238= | Silent (SNP) | VAF 92/259 reads (36%) | called by muse, mutect2, varscan2
- ZFPM2 | c.780G>A p.R260= | Silent (SNP) | VAF 105/270 reads (39%) | catalogued as COSV65872777, COSV65874675; called by muse, mutect2, varscan2
- ZFYVE28 | c.1626C>T p.A542= | Silent (SNP) | VAF 141/429 reads (33%) | catalogued as rs532995191, COSV52115253; called by muse, mutect2, varscan2
- ZNF100 | c.978T>C p.F326= | Silent (SNP) | VAF 145/408 reads (36%) | catalogued as rs761933235; called by muse, mutect2, varscan2
- ZNF18 | c.1179C>T p.T393= | Silent (SNP) | VAF 110/230 reads (48%) | called by muse, varscan2
- ZNF197 | c.105C>T p.S35= | Silent (SNP) | VAF 105/333 reads (32%) | catalogued as COSV100482113; called by muse, mutect2, varscan2
- ZNF835 | c.489G>A p.E163= | Silent (SNP) | VAF 145/495 reads (29%) | called by muse, mutect2
- ZSCAN32 | c.1191G>A p.E397= (on ENST00000396846; = p.E418= on NM_017810.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 146/403 reads (36%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148225 C>T | 5'Flank (SNP) | VAF 94/323 reads (29%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845798 G>A | 5'Flank (SNP) | VAF 42/141 reads (30%) | called by muse, mutect2, varscan2
- ANK3 | c.12596-468C>T | Intron (SNP) | VAF 94/328 reads (29%) | called by muse, varscan2
- ARHGEF4 | c.-220G>A | 5'UTR (SNP) | VAF 80/230 reads (35%) | called by muse, mutect2, varscan2
- CFAP47 | c.2844+13C>T | Intron (SNP) | VAF 98/344 reads (28%) | called by muse, mutect2, varscan2
- DTNA | c.1662+2080T>A | Intron (SNP) | VAF 93/290 reads (32%) | called by muse, mutect2, varscan2
- EBNA1BP2 | chr1:43172309 C>T | 5'Flank (SNP) | VAF 103/314 reads (33%) | catalogued as COSV52539619; called by muse, mutect2, varscan2
- FBXO24 | c.40-232G>A | Intron (SNP) | VAF 135/421 reads (32%) | called by muse, mutect2, varscan2
- GDPD1 | c.*1376G>A | 3'UTR (SNP) | VAF 89/362 reads (25%) | called by muse, mutect2, varscan2
- IKZF1 | c.161-8347C>T | Intron (SNP) | VAF 101/280 reads (36%) | catalogued as rs267601536, COSV58793065; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1640+18C>G | Intron (SNP) | VAF 120/397 reads (30%) | catalogued as rs1560099488; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+19196C>T | Intron (SNP) | VAF 68/192 reads (35%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+37698G>A | Intron (SNP) | VAF 176/475 reads (37%) | called by muse, mutect2, varscan2
- MAPK4 | c.547-10429C>T | Intron (SNP) | VAF 112/315 reads (36%) | called by muse, mutect2, varscan2
- MARCHF10 | c.383-2349C>T | Intron (SNP) | VAF 70/320 reads (22%) | called by muse, mutect2, varscan2
- OGFOD3 | c.824-1910C>T | Intron (SNP) | VAF 235/489 reads (48%) | catalogued as rs145765136, COSV57341151; called by muse, mutect2, varscan2
- PPIAP58 | chr19:29923717 G>A | 3'Flank (SNP) | VAF 87/286 reads (30%) | called by muse, mutect2, varscan2
- PTX4 | c.142-389C>T | Intron (SNP) | VAF 93/333 reads (28%) | called by muse, mutect2, varscan2
- SKOR1 | chr15:67822037 G>A | 5'Flank (SNP) | VAF 443/595 reads (74%) | catalogued as rs1340680170; called by muse, mutect2, varscan2
- SPDYE16 | chr7:76541452 C>T | 5'Flank (SNP) | VAF 94/309 reads (30%) | called by muse, mutect2, varscan2
- SYT14 | c.226+2369C>T | Intron (SNP) | VAF 91/488 reads (19%) | catalogued as rs1421785563; called by muse, mutect2, varscan2
- TENT5A | chr6:81752740 G>A | 5'Flank (SNP) | VAF 62/152 reads (41%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.1196+18C>T | Intron (SNP) | VAF 133/381 reads (35%) | called by muse, mutect2, varscan2
- VIL1 | c.1102+85C>T | Intron (SNP) | VAF 116/408 reads (28%) | called by muse, mutect2, varscan2
- VSX1 | c.627+15T>C | Intron (SNP) | VAF 53/362 reads (15%) | called by muse, mutect2, varscan2
